Somatic mutation profile of tumor specimen TCGA-B1-5398-01A (aliquot TCGA-B1-5398-01A-02D-1589-08) from TCGA case TCGA-B1-5398, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 73.4 years (26,820 days).
Specimen TCGA-B1-5398-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d05d634-9b39-477c-8c9f-b9883b859e0a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B1-5398-10A (Blood Derived Normal), aliquot TCGA-B1-5398-10A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6b9eedb-d084-4a42-94c7-06f5c8bba986

The open-access MAF lists 118 somatic variants for this specimen: 82 protein-altering or splice-affecting, 29 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 29, Frame Shift Del 9, Nonsense Mutation 8, Splice Site 5, Intron 4, Frame Shift Ins 2, Nonstop Mutation 1, 5'Flank 1, Splice Region 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1862A>G p.N621S (on ENST00000288602 / NM_001374244.1; = p.N581S on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs121913370, COSV56058108, COSV56106422, COSV56110832; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.2868-2A>G p.X956_splice (on ENST00000404938 / NM_001163941.2; = p.X511_splice on NM_178559.6) | Splice Site (SNP) | VAF 7/45 reads (16%) | catalogued as COSV51717694, COSV51720700; called by muse, mutect2, varscan2
- ADAMTS20 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.268); catalogued as COSV67137209; called by muse, mutect2
- AGR2 | c.331T>C p.Y111H | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs571596748, COSV68597289; called by muse, mutect2, varscan2
- AGR2 | c.331-1G>T p.X111_splice | Splice Site (SNP) | VAF 10/52 reads (19%) | catalogued as COSV68597292; called by muse, mutect2, varscan2
- AGXT2 | c.772T>G p.C258G | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV51489375; called by muse, mutect2
- ALDH1L2 | c.2043G>A p.K681= | Splice Region (SNP) | VAF 17/109 reads (16%) | catalogued as COSV51558814; called by muse, mutect2, varscan2
- ANGPTL3 | c.641T>A p.I214N | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV52017363; called by muse, mutect2, varscan2
- ANKRD17 | c.1489A>T p.N497Y | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58226136; called by muse, mutect2, varscan2
- ANKRD35 | c.2072G>C p.R691P | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV62911301; called by muse, mutect2, varscan2
- ARHGAP26 | c.1802T>A p.L601Q | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV50837720; called by muse, mutect2, varscan2
- ARHGEF17 | c.1757T>C p.I586T | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as COSV55236303; called by muse, mutect2, varscan2
- ARSD | c.1299-2A>G p.X433_splice | Splice Site (SNP) | VAF 7/24 reads (29%) | catalogued as COSV54202286; called by muse, mutect2, varscan2
- ASXL1 | c.308A>G p.E103G | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV60117694; called by muse, mutect2, varscan2
- ATP1B1 | c.362T>G p.M121R | Missense Mutation (SNP) | VAF 54/291 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.08); catalogued as COSV63179866; called by muse, mutect2, varscan2
- CASP4 | c.213G>A p.M71I | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV67744735; called by muse, mutect2, varscan2
- CCDC110 | c.1298A>T p.N433I | Missense Mutation (SNP) | VAF 50/250 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56872918; called by muse, mutect2, varscan2
- CCKBR | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs934379707, COSV58104416; called by muse, mutect2, varscan2
- CELSR1 | c.5852T>A p.L1951H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as COSV53097325; called by mutect2, varscan2
- CHD4 | c.1495C>T p.Q499* (on ENST00000357008 / NM_001363606.2; = p.Q512* on NM_001273.5) | Nonsense Mutation (SNP) | VAF 38/258 reads (15%) | catalogued as COSV58908160; called by muse, mutect2, varscan2
- CLDN25 | c.520A>G p.I174V | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs764144573, COSV71620411; called by muse, mutect2, varscan2
- COL18A1 | c.2921G>A p.G974D (on ENST00000359759 / NM_130444.3; = p.G739D on NM_030582.4) | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62705809; called by muse, mutect2, varscan2
- CPEB4 | c.1269T>G p.Y423* | Nonsense Mutation (SNP) | VAF 40/296 reads (14%) | catalogued as COSV54175186; called by muse, mutect2, varscan2
- DAPK1 | c.444G>C p.L148F | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63790814; called by muse, mutect2, varscan2
- DGLUCY | c.636T>A p.D212E | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as COSV56369360; called by muse, mutect2, varscan2
- DHX58 | c.443A>T p.Q148L | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV52427679; called by muse, mutect2, varscan2
- ENTPD7 | c.1295G>C p.G432A | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as COSV65112987; called by muse, mutect2, varscan2
- EPOR | c.1025T>C p.M342T | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV55801289; called by muse, mutect2, varscan2
- FBXW10 | c.773T>A p.L258* | Nonsense Mutation (SNP) | VAF 36/210 reads (17%) | catalogued as COSV100111435, COSV57321048; called by muse, mutect2, varscan2
- FIG4 | c.1506A>T p.K502N | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV57790201; called by muse, mutect2, varscan2
- GUCY1B1 | c.1563A>G p.I521M | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52375312; called by muse, mutect2, varscan2
- HAS3 | c.167T>A p.L56Q | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54708674; called by muse, mutect2, varscan2
- INPPL1 | c.3088C>T p.R1030W | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs746017563, COSV53358454; called by muse, mutect2, varscan2
- IQUB | c.1220A>G p.Y407C | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs567499713, COSV61237060, COSV61241735; called by muse, mutect2, varscan2
- ISL1 | c.478+1G>T p.X160_splice | Splice Site (SNP) | VAF 15/48 reads (31%) | catalogued as COSV57935230; called by muse, mutect2, varscan2
- KCNT1 | c.3604G>A p.V1202M (on ENST00000488444; = p.V1207M on NM_020822.3) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs766339368, COSV53708369; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF27 | c.2686A>T p.K896* | Nonsense Mutation (SNP) | VAF 16/116 reads (14%) | catalogued as COSV52830384; called by muse, mutect2, varscan2
- LRRK2 | c.2588A>T p.N863I | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV54165410; called by muse, mutect2, varscan2
- MADD | c.4441G>C p.E1481Q | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60628582; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1792C>T p.R598W | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1469001912, COSV53797215; called by muse, mutect2, varscan2
- MBD6 | c.2954C>T p.P985L | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.199); catalogued as rs768572410, COSV63075565, COSV63076084; called by muse, mutect2, varscan2
- MCHR1 | c.310A>T p.S104C | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.24); catalogued as COSV50762528; called by muse, mutect2, varscan2
- MDC1 | c.1726G>A p.D576N | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.203); catalogued as COSV64526541; called by muse, mutect2, varscan2
- MEI1 | c.1874T>G p.V625G | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV55906204; called by muse, mutect2, varscan2
- MLH3 | c.229A>T p.K77* | Nonsense Mutation (SNP) | VAF 15/91 reads (16%) | catalogued as COSV53135685; called by muse, mutect2, varscan2
- MVP | c.749T>G p.L250R | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62423124; called by muse, mutect2
- MYO5B | c.4272A>T p.K1424N | Missense Mutation (SNP) | VAF 59/450 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53227817; called by muse, mutect2, varscan2
- NDUFB5 | c.341A>C p.K114T | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV52021462; called by muse, mutect2, varscan2
- NUMA1 | c.4267G>A p.A1423T | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.205); catalogued as rs1416478637, COSV61189562; called by muse, mutect2, varscan2
- OR4N5 | c.814T>G p.S272A | Missense Mutation (SNP) | VAF 76/410 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as COSV61321082; called by muse, mutect2, varscan2
- OR5D14 | c.294C>A p.S98R | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV59457931; called by muse, mutect2
- OR5D14 | c.295T>A p.C99S | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59457938; called by muse, mutect2
- PCF11 | c.1751A>G p.N584S | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.275); catalogued as COSV53528037, COSV53537357; called by muse, mutect2, varscan2
- PPP2R5C | c.95-1G>A p.X32_splice | Splice Site (SNP) | VAF 52/289 reads (18%) | catalogued as COSV58275297; called by muse, mutect2, varscan2
- PRICKLE1 | c.1543C>T p.Q515* | Nonsense Mutation (SNP) | VAF 28/149 reads (19%) | catalogued as COSV58209472; called by muse, mutect2, varscan2
- PSME4 | c.2726A>G p.H909R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs768667528, COSV66366940; called by muse, mutect2, varscan2
- RASSF8 | c.145A>T p.T49S | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.921); catalogued as COSV51454934; called by muse, mutect2, varscan2
- RBM27 | c.2008T>G p.L670V | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.301); catalogued as COSV54593001; called by muse, varscan2
- RHOBTB1 | c.493A>T p.R165* | Nonsense Mutation (SNP) | VAF 12/112 reads (11%) | catalogued as COSV61959813; called by muse, varscan2
- SBDS | c.257A>G p.Q86R | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as COSV55888358; called by muse, mutect2, varscan2
- SCD5 | c.84G>C p.E28D | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV51102360, COSV51104217; called by muse, mutect2, varscan2
- SLC22A10 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as rs200183991; called by muse, mutect2, varscan2
- SLC39A7 | c.220G>C p.G74R | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.443); catalogued as COSV63399971; called by muse, mutect2, varscan2
- SRRM2 | c.381A>T p.L127F | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.915); catalogued as COSV57079063; called by muse, mutect2, varscan2
- TMEM220 | c.341C>G p.S114C | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59379846; called by muse, varscan2
- TPBG | c.481del p.A161Lfs*18 | Frame Shift Del (DEL) | VAF 29/200 reads (15%) | catalogued as COSV63882766; called by mutect2, pindel, varscan2
- UBA2 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs370848936; called by muse, mutect2, varscan2
- UBR3 | c.3615G>A p.M1205I | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV99773884, COSV99774488; called by muse, mutect2, varscan2
- XPO6 | c.1330A>T p.N444Y | Missense Mutation (SNP) | VAF 76/273 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV58969982; called by muse, mutect2, varscan2
- ZNF366 | c.1878C>G p.Y626* | Nonsense Mutation (SNP) | VAF 61/339 reads (18%) | catalogued as rs373642159, COSV59213955, COSV59218228; called by muse, mutect2, varscan2
- CABS1 | c.406del p.S136Pfs*4 | Frame Shift Del (DEL) | VAF 19/110 reads (17%) | called by mutect2, pindel, varscan2
- CNOT1 | c.49_52dup p.D18Gfs*26 | Frame Shift Ins (INS) | VAF 23/107 reads (21%) | called by mutect2, pindel, varscan2
- COL1A1 | c.3248C>G p.A1083G | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.215); called by muse, mutect2
- DCLK1 | c.1828_1832del p.S610Ifs*4 | Frame Shift Del (DEL) | VAF 38/171 reads (22%) | called by mutect2, pindel, varscan2
- F10 | c.996del p.T333Pfs*4 | Frame Shift Del (DEL) | VAF 25/184 reads (14%) | called by mutect2, pindel, varscan2
- FANCM | c.5752del p.Y1918Mfs*5 | Frame Shift Del (DEL) | VAF 21/103 reads (20%) | called by mutect2, pindel, varscan2
- GRIP1 | c.1588del p.I530Ffs*45 (on ENST00000359742 / NM_001379345.1; = p.I478Ffs*45 on NM_021150.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 18/98 reads (18%) | called by mutect2, pindel, varscan2
- LMBRD1 | c.553_554dup p.L185Ffs*2 (on ENST00000649011; = p.L163Ffs*2 on NM_018368.4) | Frame Shift Ins (INS) | VAF 11/84 reads (13%) | called by mutect2, pindel, varscan2
- MRC1 | c.4370A>G p.*1457Wext*15 | Nonstop Mutation (SNP) | VAF 101/570 reads (18%) | called by muse, mutect2, varscan2
- SCN11A | c.4311_4312del p.L1438Sfs*5 | Frame Shift Del (DEL) | VAF 34/138 reads (25%) | called by mutect2, pindel, varscan2
- SH3BP4 | c.2805del p.T936Lfs*4 | Frame Shift Del (DEL) | VAF 28/162 reads (17%) | called by mutect2, pindel, varscan2
- SRCAP | c.1549del p.T517Qfs*62 | Frame Shift Del (DEL) | VAF 11/74 reads (15%) | called by mutect2, pindel, varscan2
- AOX1 | c.1506C>T p.S502= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV65983455; called by muse, mutect2, varscan2
- ARID4B | c.1002A>G p.G334= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs774510125, COSV51609093; called by muse, mutect2, varscan2
- COL4A4 | c.4980G>A p.Q1660= | Silent (SNP) | VAF 84/535 reads (16%) | catalogued as COSV61635228; called by muse, mutect2, varscan2
- COL6A3 | c.9483T>A p.V3161= | Silent (SNP) | VAF 51/217 reads (24%) | catalogued as COSV55103309; called by muse, mutect2, varscan2
- FKBP4 | c.867T>G p.A289= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV50009679; called by muse, mutect2, varscan2
- GPR22 | c.960T>A p.S320= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as COSV51760914; called by muse, mutect2, varscan2
- HSPA1L | c.1476C>A p.A492= | Silent (SNP) | VAF 32/185 reads (17%) | catalogued as COSV65151055; called by muse, mutect2, varscan2
- ITPRID2 | c.514T>C p.L172= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV57475385; called by muse, mutect2, varscan2
- LAIR1 | c.360G>T p.V120= | Silent (SNP) | VAF 31/179 reads (17%) | catalogued as COSV57309209; called by muse, mutect2, varscan2
- LBP | c.633T>G p.P211= | Silent (SNP) | VAF 25/180 reads (14%) | catalogued as COSV54142674; called by muse, mutect2, varscan2
- MCC | c.435T>A p.S145= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV56734049; called by muse, mutect2
- NEIL3 | c.249C>G p.L83= | Silent (SNP) | VAF 29/221 reads (13%) | catalogued as rs762225312, COSV52812840; called by muse, mutect2, varscan2
- NFKB2 | c.300C>T p.D100= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV51874727; called by muse, mutect2, varscan2
- NGLY1 | c.1350T>A p.P450= | Silent (SNP) | VAF 45/124 reads (36%) | catalogued as COSV54989637; called by muse, mutect2, varscan2
- OR51T1 | c.967A>C p.R323= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as rs1226824983, COSV59027469; called by muse, mutect2
- PCBP1 | c.75A>G p.V25= | Silent (SNP) | VAF 37/154 reads (24%) | catalogued as COSV57851657; called by muse, mutect2, varscan2
- PCDHA8 | c.1410G>C p.P470= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as rs202126810, COSV65334668, COSV65339563; called by muse, mutect2, varscan2
- PDZD2 | c.648C>G p.T216= | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as COSV56869107; called by muse, mutect2, varscan2
- PER2 | c.306T>G p.S102= | Silent (SNP) | VAF 19/112 reads (17%) | catalogued as COSV54526613; called by muse, mutect2, varscan2
- PSMD5 | c.594A>G p.E198= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV52961705; called by muse, mutect2, varscan2
- SCAF11 | c.3831A>T p.P1277= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV65478468; called by muse, mutect2, varscan2
- SCG3 | c.1143A>G p.G381= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV55021605; called by muse, mutect2, varscan2
- SCN1A | c.354G>A p.R118= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as rs121917959, CM081422, COSV57682496; called by muse, mutect2, varscan2
- SLC38A8 | c.636T>C p.P212= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV55308907; called by muse, mutect2, varscan2
- SPTAN1 | c.876T>C p.A292= | Silent (SNP) | VAF 41/189 reads (22%) | catalogued as rs762428150, COSV100823202, COSV63989210; called by muse, mutect2, varscan2
- USP15 | c.2742T>A p.T914= (on ENST00000280377 / NM_001351159.2; = p.T885= on NM_006313.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV54796931; called by muse, mutect2, varscan2
- ZNF254 | c.978A>G p.E326= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs1192663298, COSV61644289; called by muse, mutect2, varscan2
- ZNF385B | c.1305T>C p.P435= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1234974890, COSV100415984; called by muse, mutect2, varscan2
- ZNF646 | c.3078G>A p.E1026= | Silent (SNP) | VAF 29/207 reads (14%) | catalogued as COSV54924636, COSV54926066; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498942 G>T | 5'Flank (SNP) | VAF 18/108 reads (17%) | catalogued as rs1455276533; called by muse, mutect2, varscan2
- BAG5 | c.-16T>A | 5'UTR (SNP) | VAF 29/166 reads (17%) | catalogued as COSV99914824; called by muse, mutect2, varscan2
- CNOT3 | c.2037+208T>A | Intron (SNP) | VAF 10/31 reads (32%) | catalogued as COSV99651742; called by muse, mutect2, varscan2
- GLS | c.1650+1192A>G | Intron (SNP) | VAF 11/57 reads (19%) | catalogued as rs1300910114, COSV100290003; called by muse, mutect2, varscan2
- LINC01588 | n.925A>G | RNA (SNP) | VAF 22/145 reads (15%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-23329G>A | Intron (SNP) | VAF 39/174 reads (22%) | catalogued as rs756391897, COSV59392090; called by muse, varscan2
- UGT1A6 | c.862-23308A>G | Intron (SNP) | VAF 36/221 reads (16%) | catalogued as COSV59395933; called by muse, varscan2
